Somatic mutation profile of tumor specimen TCGA-55-6982-01A (aliquot TCGA-55-6982-01A-11D-1945-08) from TCGA case TCGA-55-6982, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-55-6982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d040d578-1baf-46e8-8d98-1d2b89a94141.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6982-11A (Solid Tissue Normal), aliquot TCGA-55-6982-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/059df941-5be5-4118-a3ce-03b8eda4d9e4

The open-access MAF lists 228 somatic variants for this specimen: 169 protein-altering or splice-affecting, 55 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 55, Nonsense Mutation 10, Frame Shift Del 5, 3'UTR 2, Splice Site 2, Intron 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3028_3028+5del p.X1010_splice | Splice Site (DEL) | VAF 9/51 reads (18%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AAMP | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV50306885; called by muse, mutect2, varscan2
- ABHD1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as COSV53204462; called by muse, mutect2, varscan2
- ACIN1 | c.2770-1G>C p.X924_splice | Splice Site (SNP) | VAF 9/95 reads (9%) | catalogued as COSV52973235; called by muse, mutect2, varscan2
- ADCY8 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773742788, COSV53896347; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58441289; called by muse, mutect2, varscan2
- ADGRG4 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV54949340; called by muse, mutect2, varscan2
- AGL | c.3250C>G p.L1084V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV54048134; called by muse, mutect2, varscan2
- AHNAK | c.12067C>G p.L4023V | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57203567; called by muse, mutect2, varscan2
- AHR | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV54121607; called by muse, mutect2
- ANKRD17 | c.5641C>T p.L1881F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV58215449; called by muse, mutect2, varscan2
- APCS | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as rs879661012, COSV54817191; called by muse, mutect2
- APOA4 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV63359993; called by muse, mutect2
- ARHGEF10 | c.3977C>A p.A1326D (on ENST00000398564; = p.A1301D on NM_014629.4) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV50642515; called by muse, mutect2
- ARMCX6 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV62680570, COSV62680582; called by muse, mutect2, varscan2
- ARSJ | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV59536684; called by muse, mutect2, varscan2
- ASXL3 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV52457230; called by muse, mutect2, varscan2
- ATP10D | c.1154C>G p.P385R | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56703808; called by muse, mutect2
- ATP5F1B | c.1396C>G p.Q466E | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV51631567; called by muse, mutect2
- BLZF1 | c.632A>C p.Q211P | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61392747; called by muse, mutect2, varscan2
- C10orf120 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as COSV61491613, COSV61492364; called by muse, mutect2, varscan2
- CACNA1C | c.2828T>G p.I943S | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100217203; called by muse, mutect2
- CCDC138 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV54564251; called by muse, mutect2
- CCR6 | c.604C>A p.Q202K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV59473875; called by muse, mutect2, varscan2
- CD1E | c.147C>A p.S49R | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63769950; called by muse, mutect2
- CDH22 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64836454, COSV64839976; called by muse, mutect2
- CDR2 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1179890644, COSV51675205; called by muse, mutect2, varscan2
- CDR2 | c.788C>G p.S263* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | catalogued as COSV51675214; called by muse, mutect2
- CDYL | c.478G>T p.E160* (on ENST00000328908 / NM_001368125.1; = p.E106* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59358284, COSV59359622; called by muse, mutect2, varscan2
- CKAP5 | c.1174A>G p.T392A | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56364085; called by muse, mutect2, varscan2
- CLCN1 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367354; called by muse, mutect2, varscan2
- CLCN2 | c.1581G>C p.Q527H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1210243477, COSV55599186; called by muse, mutect2, varscan2
- CLDN17 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748470055, COSV54522205; called by muse, mutect2, varscan2
- CNOT6L | c.773G>T p.G258V (on ENST00000504123 / NM_001286790.2; = p.G253V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53697127; called by mutect2, varscan2
- COL6A3 | c.6661G>C p.E2221Q | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55079624; called by muse, mutect2, varscan2
- COL6A3 | c.3156G>C p.Q1052H | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV55079635; called by muse, mutect2
- CPS1 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs970256252, COSV51802040; called by muse, mutect2, varscan2
- CPXM1 | c.220del p.V74Sfs*3 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as COSV66046024; called by mutect2, pindel, varscan2
- DISP3 | c.1743C>G p.F581L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV53820229; called by muse, mutect2, varscan2
- DNAH3 | c.9550G>A p.E3184K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54503269; called by muse, mutect2
- DPP10 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59664588; called by muse, mutect2
- DSTN | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV55712244; called by muse, mutect2, varscan2
- EIF4G1 | c.1033C>T p.L345F (on ENST00000346169 / NM_198241.3; = p.L149F on NM_004953.5) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs1251323549, COSV59989114; called by muse, mutect2, varscan2
- EIF4G1 | c.1639C>T p.Q547* (on ENST00000346169 / NM_198241.3; = p.Q351* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV59989123; called by muse, mutect2
- EMILIN2 | c.2277G>C p.K759N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54420989, COSV54424811; called by muse, mutect2, varscan2
- ERC1 | c.1357C>G p.Q453E | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100706844, COSV61691525; called by muse, mutect2
- FAM71A | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54234603; called by muse, mutect2
- FBXL7 | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1219818114, COSV61641181; called by muse, mutect2, varscan2
- FGFR4 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52800772; called by muse, mutect2, varscan2
- FGL1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV67711793; called by muse, mutect2, varscan2
- FOLH1 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as COSV57045616; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1754C>G p.S585* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | catalogued as COSV58545729; called by muse, mutect2
- FYCO1 | c.2092A>G p.K698E | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1348375024, COSV56113507; called by muse, mutect2, varscan2
- GAPT | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs370924428; called by muse, mutect2, varscan2
- GORASP2 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV52200827; called by muse, mutect2
- GPR31 | c.530G>C p.W177S | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV64761117; called by muse, mutect2, varscan2
- GRID2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56173140; called by muse, varscan2
- GRM5 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV59590648; called by muse, mutect2, varscan2
- HECW2 | c.630G>C p.K210N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477028438, COSV53649436; called by muse, mutect2, varscan2
- HEXA | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs748584487, COSV51505150; called by muse, mutect2, varscan2
- HGF | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55945504; called by muse, varscan2
- HIP1 | c.132C>G p.I44M | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV61183247; called by muse, mutect2
- HLA-DQB1 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV66569122; called by muse, mutect2, varscan2
- HNRNPK | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61088207; called by muse, mutect2, varscan2
- HOXB6 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53312109; called by muse, mutect2
- HS3ST4 | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58801627, COSV58828306; called by muse, mutect2, varscan2
- HTR4 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen probably damaging (0.953); catalogued as COSV58789525; called by muse, mutect2, varscan2
- IFI16 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.293); catalogued as COSV55530950; called by muse, mutect2, varscan2
- JMJD6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs1250052982, COSV57970112; called by muse, mutect2
- KCTD19 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58571111; called by muse, mutect2, varscan2
- KDM3B | c.3560G>A p.R1187K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV58687938; called by muse, mutect2, varscan2
- KHDRBS1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV56980660; called by muse, mutect2
- KLHL30 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV59974183; called by muse, mutect2
- LDAH | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV52968420; called by muse, mutect2, varscan2
- LMO7 | c.2422G>C p.E808Q (on ENST00000357063; = p.E489Q on NM_005358.5) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV58529796; called by muse, mutect2, varscan2
- LRBA | c.3547A>G p.T1183A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV63949859; called by muse, mutect2, varscan2
- LRP2 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55540845; called by muse, mutect2, varscan2
- LRRC7 | c.4486G>C p.G1496R (on ENST00000651989 / NM_001370785.2; = p.G1416R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50410900, COSV50444657; called by muse, mutect2, varscan2
- LSM3 | c.107A>T p.D36V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53203589; called by muse, mutect2, varscan2
- MACF1 | c.16204G>A p.D5402N (on ENST00000372915; = p.D3335N on NM_012090.5) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV57105668; called by muse, mutect2
- MAPKAPK5 | c.954G>T p.Q318H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV73436042; called by muse, mutect2, varscan2
- MB21D2 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MFSD4A | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV65655987; called by mutect2, varscan2
- MORC2 | c.2745C>G p.L915= (on ENST00000397641 / NM_001303256.3; = p.L853= on NM_014941.3) | Splice Region (SNP) | VAF 13/78 reads (17%) | catalogued as COSV53196228, COSV53196974; called by muse, mutect2, varscan2
- MRGPRX1 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 25/659 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57105890, COSV99044146; called by muse, mutect2
- MTRR | c.670G>C p.D224H (on ENST00000264668; = p.D197H on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs748186027, COSV104391195, COSV52941625; called by muse, varscan2
- NFE2L2 | c.1538A>T p.N513I | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67960132; called by muse, mutect2
- NLRC4 | c.1540C>G p.Q514E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1483771516, COSV100707482, COSV61591349; called by muse, mutect2, varscan2
- NUMA1 | c.5479G>C p.E1827Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV52619725; called by muse, mutect2, varscan2
- OR2A25 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV68716863; called by muse, mutect2, varscan2
- OR4C15 | c.523C>A p.R175S (on ENST00000314644; = p.R121S on NM_001001920.2) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4D11 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV57584595; called by muse, mutect2, varscan2
- OR4D6 | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55658945; called by muse, mutect2
- OR51M1 | c.591A>G p.I197M | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.495); catalogued as COSV60783768; called by muse, mutect2
- OR51S1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1439269302, COSV59057216, COSV59057408; called by muse, mutect2
- OR52L1 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV59985677; called by muse, mutect2, varscan2
- OR7A17 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.231); catalogued as COSV59413768; called by muse, mutect2
- OTP | c.381C>G p.H127Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60568455; called by muse, varscan2
- PGBD1 | c.1840C>G p.L614V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV52551292, COSV99460385; called by muse, mutect2, varscan2
- PHOX2B | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV56928256; called by muse, mutect2, varscan2
- PIK3C3 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56275982, COSV56284161; called by muse, mutect2, varscan2
- PIK3R3 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV53104327; called by muse, mutect2, varscan2
- PLIN3 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55734057; called by mutect2, varscan2
- PLK4 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV54636270; called by muse, mutect2
- PMS2 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.074); catalogued as rs371011390, COSV56219614, COSV56221488; ClinVar: uncertain significance / not provided / conflicting interpretations of pathogenicity / benign; called by muse, mutect2, varscan2
- PNPLA8 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57551312; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV53450766; called by muse, varscan2
- PPAN-P2RY11 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs752291134, COSV53450791; called by muse, varscan2
- PRKG2 | c.1887C>G p.F629L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as COSV52319108, COSV52332045; called by muse, mutect2, varscan2
- PRPF3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV61393833; called by muse, mutect2
- PTPRR | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as COSV51724852, COSV51735081; called by muse, mutect2
- RBL2 | c.2360G>C p.G787A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV50872965; called by muse, mutect2
- RBM4 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV59518026; called by muse, mutect2, varscan2
- RC3H2 | c.1094A>C p.D365A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59010274; called by muse, mutect2
- RPAP1 | c.3992G>A p.R1331H | Missense Mutation (SNP) | VAF 42/329 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs147536655; called by muse, mutect2, varscan2
- RSPO2 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs149399382; called by mutect2, varscan2
- SEC13 | c.625G>C p.E209Q (on ENST00000350697 / NM_183352.3; = p.E212Q on NM_030673.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.323); catalogued as COSV100491424, COSV61601203; called by muse, mutect2, varscan2
- SECISBP2L | c.1991C>A p.S664* (on ENST00000559471 / NM_001193489.2; = p.S619* on NM_014701.4) | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV55932659; called by muse, mutect2, varscan2
- SEPTIN2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as COSV63471920; called by muse, mutect2, varscan2
- SLC22A14 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV56196563, COSV56197600; called by muse, mutect2, varscan2
- SMPDL3A | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440742950, COSV63755113; called by muse, mutect2
- SPATA31D1 | c.3387G>C p.K1129N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.882); catalogued as COSV61192748; called by muse, mutect2, varscan2
- STIP1 | c.1497G>C p.M499I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54176827, COSV54180541; called by muse, mutect2
- SUCO | c.3694G>C p.D1232H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55261967; called by muse, mutect2, varscan2
- SUSD5 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV58875720; called by muse, mutect2, varscan2
- TBC1D1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs752931895, COSV54713521; called by mutect2, varscan2
- TCHH | c.3736G>C p.E1246Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.578); catalogued as rs1557809739, COSV64272813; called by muse, mutect2
- TEX45 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); catalogued as COSV64462674; called by muse, mutect2, varscan2
- THAP4 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV67190655; called by muse, mutect2, varscan2
- TLN1 | c.5409G>A p.M1803I | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs879011046, COSV59204053; called by muse, mutect2, varscan2
- TLR7 | c.1155G>C p.L385F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66123503; called by muse, mutect2
- TMEM179B | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53667261; called by muse, mutect2, varscan2
- TMEM209 | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV52832982; called by muse, mutect2
- TMPRSS15 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs908921511, COSV53034768; called by muse, mutect2
- TOR1AIP2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as COSV62625537; called by muse, mutect2
- TRHDE | c.2613C>G p.F871L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53832593, COSV53835459; called by muse, mutect2
- TRIM68 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs139399398; called by muse, mutect2, varscan2
- TRPC4 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58990530; called by muse, mutect2, varscan2
- TTC37 | c.1960C>G p.Q654E | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62453385; called by muse, mutect2
- TTLL3 | c.1717G>A p.D573N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59613472; called by muse, mutect2, varscan2
- TTN | c.52530G>C p.K17510N (on ENST00000591111; = p.K10086N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | PolyPhen possibly damaging (0.787); catalogued as COSV59887029; called by muse, mutect2
- TTN | c.44655G>C p.L14885F (on ENST00000591111; = p.L7461F on NM_003319.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV59887055; called by muse, mutect2, varscan2
- UBE2Q2 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV51191891; called by mutect2, varscan2
- UBXN1 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53656100; called by muse, mutect2, varscan2
- UBXN1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53656121; called by mutect2, varscan2
- USP47 | c.3640G>C p.D1214H (on ENST00000399455 / NM_001372095.1; = p.D1126H on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV59693746, COSV59693798; called by muse, mutect2
- VAV3 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV58377072; called by muse, varscan2
- VMA21 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57755765; called by muse, mutect2, varscan2
- VPS33A | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57356004; called by muse, varscan2
- WDFY3 | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV55693413, COSV99884011; called by muse, mutect2, varscan2
- ZDBF2 | c.2993C>G p.S998* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV65621904; called by muse, mutect2, varscan2
- ZFHX3 | c.8502C>G p.D2834E | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.991); catalogued as COSV51708520; called by muse, mutect2, varscan2
- ZNF107 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV61326820; called by muse, mutect2, varscan2
- ZNF518B | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV58721310; called by muse, mutect2, varscan2
- ZNF688 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV56299917, COSV56300306, COSV99794398; called by muse, varscan2
- ZNF804A | c.1933G>T p.A645S | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV56435494, COSV56472104; called by muse, mutect2
- ZNF835 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs759907260, COSV73379643; called by muse, mutect2, varscan2
- ZP4 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1262012364, COSV63910895; called by muse, mutect2, varscan2
- ARID1B | c.5775G>T p.Q1925H | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ARID1B | c.5776G>T p.D1926Y | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EXOC2 | c.25del p.V10* | Frame Shift Del (DEL) | VAF 21/223 reads (9%) | called by mutect2, pindel
- GRIN2A | c.40del p.A14Pfs*21 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- IGHV7-81 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INHBA | c.1089del p.S364Pfs*33 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by mutect2, varscan2
- PAQR6 | c.573_574insAGCCTAT p.P192Sfs*54 (on ENST00000292291 / NM_001272108.2; = p.P86Sfs*54 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel
- SIM2 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- VPS33A | c.923del p.G308Afs*53 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by pindel, varscan2
- ZBTB26 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- ZNF331 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.103); called by muse, mutect2
- ADAMTS16 | c.2253C>T p.L751= | Silent (SNP) | VAF 22/388 reads (6%) | called by muse, mutect2
- ADGRG1 | c.897C>T p.F299= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65635181; called by muse, mutect2, varscan2
- ANXA3 | c.204G>T p.L68= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV53713139; called by muse, varscan2
- APLP1 | c.549C>T p.S183= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV55701653; called by muse, mutect2, varscan2
- ARHGEF5 | c.4107C>T p.I1369= | Silent (SNP) | VAF 15/262 reads (6%) | catalogued as COSV50207654; called by muse, mutect2
- ATP5F1B | c.885C>T p.D295= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV56260276; called by muse, mutect2, varscan2
- ATXN1 | c.1386C>T p.I462= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs754215904, COSV55208292; called by muse, mutect2, varscan2
- C19orf57 | c.81C>T p.D27= | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as COSV60967180; called by muse, mutect2, varscan2
- CBY1 | c.380G>A p.*127= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53263782; called by muse, mutect2, varscan2
- CDH7 | c.1302C>T p.I434= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1256184442, COSV59881516; called by muse, mutect2, varscan2
- DENND2A | c.2844C>T p.V948= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV52047755; called by muse, mutect2
- DNM3 | c.1068C>G p.L356= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV62453043; called by muse, mutect2, varscan2
- EFNB1 | c.762C>T p.I254= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52660978; called by muse, mutect2, varscan2
- FKBP6 | c.462C>T p.L154= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV52718798; called by muse, mutect2
- FLT1 | c.3567C>T p.F1189= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs868190326, COSV56717750; called by muse, mutect2, varscan2
- GCNT1 | c.816C>G p.V272= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV65056870, COSV65057808; called by muse, mutect2
- GRIN2A | c.663G>A p.K221= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- GSG1 | c.534C>T p.F178= (on ENST00000651961 / NM_001080555.4; = p.H184Y on NM_031289.5) | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV52192495; called by muse, mutect2, varscan2
- H2AC21 | c.190C>T p.L64= | Silent (SNP) | VAF 6/81 reads (7%) | catalogued as COSV58611244; called by muse, mutect2
- HMCN1 | c.11679C>G p.V3893= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV54876957; called by muse, mutect2
- IL20RA | c.1563C>T p.L521= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as rs747454638, COSV57356346, COSV57357843; called by muse, mutect2
- IL4I1 | c.414C>T p.F138= | Silent (SNP) | VAF 13/107 reads (12%) | catalogued as COSV62008621; called by muse, mutect2, varscan2
- ITPR3 | c.6051C>G p.L2017= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV65405652; called by muse, mutect2, varscan2
- LRRC4C | c.1467G>A p.V489= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV53418200; called by muse, mutect2, varscan2
- MAB21L2 | c.162C>T p.S54= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV58260776; called by muse, mutect2, varscan2
- MEAF6 | c.330C>A p.L110= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV56162629; called by muse, varscan2
- MEGF10 | c.3309G>A p.K1103= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV57244958; called by muse, mutect2
- NINL | c.2076C>T p.G692= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV53998571; called by muse, mutect2, varscan2
- NSD2 | c.3294C>T p.D1098= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs1172121091, COSV56386459; called by muse, mutect2, varscan2
- OR2T34 | c.597C>T p.L199= | Silent (SNP) | VAF 28/357 reads (8%) | catalogued as rs1352507435, COSV60899592; called by muse, mutect2
- OR2V2 | c.174C>T p.T58= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as COSV60314730, COSV60315002; called by muse, mutect2, varscan2
- OR6C6 | c.459C>T p.I153= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs1251164975, COSV64455446; called by muse, mutect2, varscan2
- OR7G1 | c.249G>A p.V83= | Silent (SNP) | VAF 19/194 reads (10%) | catalogued as COSV53316968; called by muse, mutect2, varscan2
- PCDHGA6 | c.1680C>T p.P560= | Silent (SNP) | VAF 30/224 reads (13%) | catalogued as rs1366118961, COSV53898426, COSV99528614; called by muse, mutect2, varscan2
- PCGF2 | c.546C>T p.R182= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- PLA2R1 | c.4221G>A p.L1407= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV51774953; called by muse, mutect2, varscan2
- PTK7 | c.1644G>A p.V548= | Silent (SNP) | VAF 10/156 reads (6%) | catalogued as rs939275149, COSV57846361; called by muse, mutect2
- RYR2 | c.4923C>T p.I1641= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as rs1409843006, COSV63661849; called by muse, mutect2
- SCN3A | c.1254G>A p.L418= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV51801358; called by muse, mutect2, varscan2
- SEMA5A | c.3165C>G p.L1055= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV66784650; called by muse, mutect2, varscan2
- SLC12A7 | c.415C>T p.L139= | Silent (SNP) | VAF 21/310 reads (7%) | catalogued as COSV53754444; called by muse, mutect2
- SORCS1 | c.1215G>C p.P405= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV53841549, COSV53861871; called by muse, mutect2
- STAP2 | c.84G>A p.K28= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV53655808; called by muse, mutect2, varscan2
- STARD13 | c.2052G>T p.L684= (on ENST00000336934 / NM_001243476.3; = p.L566= on NM_052851.3) | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV55227151; called by muse, mutect2, varscan2
- TDRD7 | c.2451T>C p.V817= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV62428297; called by muse, mutect2, varscan2
- TGFB1I1 | c.96C>T p.L32= (on ENST00000394863 / NM_001042454.3; = p.L15= on NM_015927.4) | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV62357189; called by muse, mutect2, varscan2
- TMEM26 | c.81G>C p.V27= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as COSV67492533; called by muse, mutect2, varscan2
- TRHR | c.879C>T p.S293= | Silent (SNP) | VAF 27/288 reads (9%) | catalogued as rs767535320, COSV61232803; called by muse, mutect2
- TRO | c.1887G>A p.K629= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV51497449; called by muse, mutect2
- TTN | c.76929C>T p.V25643= (on ENST00000591111; = p.V18219= on NM_003319.4) | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as COSV59887010, COSV60220349; called by muse, mutect2, varscan2
- VPS35L | c.2166C>A p.L722= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV51977123; called by muse, mutect2, varscan2
- XCR1 | c.333C>T p.I111= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV58568910; called by muse, mutect2, varscan2
- ZDHHC18 | c.492G>A p.Q164= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV65145110; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1362C>G p.L454= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56271705; called by muse, mutect2, varscan2
- ZSCAN25 | c.213G>A p.L71= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV53552107, COSV53553960; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3587G>T | 3'UTR (SNP) | VAF 23/104 reads (22%) | catalogued as rs1348104468, COSV53971342; called by muse, mutect2, varscan2
- ELP4 | c.1147-19981G>C | Intron (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- RPS2 | c.375+48C>G | Intron (SNP) | VAF 6/27 reads (22%) | catalogued as rs765852789, COSV99238755; called by muse, mutect2, varscan2
- WNT3A | c.*838G>A | 3'UTR (SNP) | VAF 14/131 reads (11%) | catalogued as COSV99469147; called by muse, mutect2, varscan2
